TCGA case TCGA-G3-AAV2 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1724c96a-2aa3-43d4-992a-08af948c0f45

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 50.3 years (18,363 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 372 days (1.0 years); Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 295 days; Disease response: Tumor Free.
- Days to follow up: 372 days (1.0 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Total Bilirubin 0.7 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.4].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.1].
- Alpha Fetoprotein 4 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 10].
- Platelets 110 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Albumin 4.2 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.3; Blood test normal range upper: 4.8].
- Creatinine 1 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.4].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis C Infection; Viral hepatitis serology tests: Hepatitis C Virus RNA / Hepatitis B Surface Antigen / HBV Surface Antibody / Hepatitis C Antibody.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G3-AAV2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 500 mg.
  Slide TCGA-G3-AAV2-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-G3-AAV2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G3-AAV2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy; New tumor event diagnosis indicator: No.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis C Virus RNA; Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 372 days; disease-specific survival: no event (censored), 372 days; disease-free interval: no event (censored), 372 days; progression-free interval: no event (censored), 372 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G3-AAV2-01A-11D-A36W-01): tumor purity 0.85, ploidy 2.09, whole-genome doublings 0.
